Surgical pathology report (de-identified scan), TCGA case TCGA-19-5959, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-5959-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS

CGA-19-5959

A., B. LEFT PARIETAL MASS, REMOVAL:

-- GLIOBLASTOMA MULTIFORME (WHO GRADE IV) DEMONSTRATING FOCAL OLIGODENDROGLIAL DIFFERENTIATION.

C. SPECIMEN LABELED INFILTRATED BRAIN, REMOVAL:

-- GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

Electronically Signed Out By

By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consultation:

A. Microscopic and Touch imprint: high grade astrocytoma.

Clinical History:

Left brain neoplasm

Specimens Submitted As:

A: LEFT PARIETAL MASS

B: LEFT PARIETAL MASS

C: INFILTRATED BRAIN

Gross Description:

A: Received fresh for intraoperative consultation, labeled with patient's name, hospital number, and "left parietal mass" are multiple pink-tan soft tissue fragments, 1.2 x 0.6 x 0.9 cm in aggregate. A touch imprint is performed. A portion is sent for frozen section. The specimen is submitted entirely in 2 cassettes.

B: Received fresh, labeled with the patient's name and number, and "A-perm tumor", are multiple irregular, opaque white to pink-tan to red, soft tissue fragments measuring in aggregate 2.2 x 2.0 x 0.6 cm. A portion of the specimen is submitted to . The remaining tissue is submitted entirely in one cassette.

C: Received fresh, postfixed in formalin, labeled with the patient's name and number, and "B-inf brain" are multiple irregular, opaque white to tan, soft, cerebriform tissue fragments measuring in aggregate 4.0 x 3.4 x 1.0 cm. Submitted entirely in three cassettes.

Summary of the cassettes:

Specimen	Label	Site
A	1FS	representative section of the specimen
	2	remainder of the specimen

Source: NCI Genomic Data Commons file 6dded2e7-d366-4ee6-b904-2baac1e345f8 (TCGA-19-5959.FD4C35F4-5FD4-49C5-8D6A-4F39DBA0BB49.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).